Somatic mutation profile of tumor specimen TARGET-10-PASHXL-09A (aliquot TARGET-10-PASHXL-09A-01D) from TARGET case TARGET-10-PASHXL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.5 years (4,942 days).
Specimen TARGET-10-PASHXL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31b637dc-43cc-41ed-95a8-bceb93ca7478.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASHXL-14A (Bone Marrow Normal), aliquot TARGET-10-PASHXL-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae9f4f4d-3c37-442d-ab48-d0c484779274

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, 5'UTR 1, Intron 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 52/55 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP8A2 | c.1175T>C p.F392S | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54975251; called by muse, mutect2, varscan2
- CFAP20DC | c.937G>T p.A313S (on ENST00000482387 / NM_001351530.2; = p.A188S on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV55927038; called by muse, mutect2, varscan2
- CNR1 | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); catalogued as rs149335541, COSV62991035; called by muse, mutect2, varscan2
- JAM3 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745951708, COSV54449892; called by muse, mutect2, varscan2
- LAMC1 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199151085, COSV51145600, COSV51173264; called by muse, mutect2, varscan2
- RSPH6A | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs766382171, COSV55575137; called by muse, mutect2, varscan2
- SYTL5 | c.1970G>T p.C657F | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52905188; called by muse, mutect2, varscan2
- TARBP1 | c.4339G>A p.E1447K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as COSV50202812; called by muse, mutect2, varscan2
- USP7 | c.1019_1020insCC p.S341Rfs*13 | Frame Shift Ins (INS) | VAF 9/19 reads (47%) | catalogued as COSV61218487; called by mutect2, varscan2*
- VSTM1 | c.247T>G p.F83V | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV58076679; called by muse, mutect2, varscan2
- ZNF16 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs200923173, COSV52765427; called by muse, mutect2, varscan2
- ADAMTS16 | c.2091A>G p.K697= | Silent (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2, varscan2
- FKTN | c.306G>A p.K102= | Silent (SNP) | VAF 46/99 reads (46%) | called by muse, mutect2, varscan2
- PSD4 | c.777C>T p.N259= | Silent (SNP) | VAF 45/83 reads (54%) | called by muse, mutect2, varscan2
- RSPO1 | c.-270C>A | 5'UTR (SNP) | VAF 13/40 reads (33%) | catalogued as rs1217456757; called by muse, mutect2, varscan2
- SNORD116-18 | n.69G>A | RNA (SNP) | VAF 45/90 reads (50%) | catalogued as rs533347600; called by muse, mutect2, varscan2
- TDG | c.24-3900G>T | Intron (SNP) | VAF 39/76 reads (51%) | called by muse, mutect2, varscan2
